Surgical pathology report (de-identified scan), TCGA case TCGA-RX-A8JQ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Minnesota, specimen TCGA-RX-A8JQ-01A (Primary Tumor).

[page 1 of 4]
Date of procurement:

SPECIMEN(S):

A: Left adrenal mass

B: Retroperitoneal mass

C: Retroperitoneal mass #2

FINAL DIAGNOSIS:

A. Adrenal gland, left "mass", resection:

- Paraganglioma, extra-adrenal
- Tumor site: Extra adrenal (the tumor is located 0.3 cm from the left adrenal gland)
- Tumor size: 3.5 cm greatest dimension
- Margins: The tumor infiltrates into adjacent adipose tissue and focally extends to the inked resection surface
- Mitosis: 1-2/10hpf
- Necrosis: Absent
- Adjacent adrenal gland with no histopathologic change

B. Soft tissue, retroperitoneal mass, biopsy:

- Portion of benign ganglion
- No neoplasm seen

ICD-O-3
Paraganglioma, extra-adrenal NOS
8693/1
Site C4CF 0.3cm from adrenal gland C48.0
path Retroperitoneum C48.0
JW 11/27/14

[page 2 of 4]
C. Soft tissue, retroperitoneal mass #2, biopsy:

- Portion of benign ganglion
- No neoplasm seen

COMMENT:

Permanent sections confirm the intraoperative consultation diagnosis of paraganglioma. The tumor cells show strong diffuse positive staining for chromogranin and synaptophysin, and absence of staining for inhibin.

The proliferative fraction as estimated by visual inspection of KI-67 is low (focally less than 5% at most).

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a year-old male with an adrenal mass, pheochromocytoma. Operative procedure: Left adrenalectomy.

GROSS:

Three containers are received, each labeled with the patient's name, and hospital identification number.

[page 3 of 4]
A. The first container is labeled "left adrenal mass." The specimen consists of an adrenal gland with attached yellow lobulated fibrofatty tissue weighing 56.0 gm and measuring 9.3 x 4.5 x 3.6 cm. A large nodule is palpable along the mid superior surface measuring 3.5 x 3.5 x 2.8 cm. This area is inked black for identification. Sectioning reveals an orange- brown mass which extends to within 0.1 cm of the inked margin. On further sectioning, the mass has no continuity with the adrenal gland but is located within 0.3 cm of the adrenal gland separated by the perirenal adipose tissue. A representative section of the tumor is selected and submitted for frozen section as AFS1. Additional sections are submitted in six cassettes.

B. The second container is received fresh and is labeled "retroperitoneal mass." The specimen consists of two tan-red soft tissue fragments, each measuring 0.2 cm in greatest dimension, entirely submitted for frozen section as BFS1.

C. The third container is labeled "retroperitoneal mass #2." The specimen consists of one tan-yellow soft tissue fragment measuring 0.3 x 0.1 x 0.1 cm, entirely submitted for frozen section as CFS1.

Note: representative tissue is procured was procured for potential future studies from specimen A.

Summary of sections:

[page 4 of 4]
AFS1 - left adrenal mass.

A2 through A4 - left adrenal gland and nearest tumor.

A5 and A6 - tumor with capsule.

A7 - left adrenal gland, random.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

AFS1 - Adrenal gland, left, mass, excision:

"Pheochromocytoma/paraganglioma."

BFS1 - Retroperitoneal mass: "Benign ganglion, negative for pheochromocytoma."

CFS1 - Retroperitoneal mass #2: "Benign ganglion, negative for pheochromocytoma."

MICROSCOPIC:

Microscopic evaluation is performed.

Reviewer Initials	AW	Reviewed: 10/25/13

Source: NCI Genomic Data Commons file 85231004-a72a-440b-ada6-291fadc51166 (TCGA-RX-A8JQ.F3522CAB-4F4E-4AB2-BE3C-E0AC4C205B76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).